Gene-level copy-number profile of tumor specimen HCM-CSHL-0078-C25-06A from HCMI case HCM-CSHL-0078-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 72.6 years (26,533 days).
Specimen HCM-CSHL-0078-C25-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4a393f5f-3913-4f10-acd7-73aa270bbaeb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0078-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,878 have no estimate.
https://portal.gdc.cancer.gov/files/90ea6d3b-1d75-4adc-b240-1b3ba3fa1ad1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 532; copy number 1: 2,414; copy number 2: 18,859; copy number 3: 13,040; copy number 4: 12,969; copy number 5: 6,124; copy number 6: 3,349; copy number 7: 135; copy number 8: 361; copy number 9: 269; copy number 10: 89; copy number 11: 38; copy number 12: 18; copy number 13: 13; copy number 14: 14; copy number 15: 191; copy number 16: 47; copy number 17: 80; copy number 18: 25; copy number 22: 23; copy number 25: 37; copy number 26: 7; copy number 28: 16; copy number 29: 95.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–22,128,103, 8 genes (within-gene range 0–4): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10,931 genes in 42 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:84,078,062–84,238,498, 1 gene, copy number 10 (within-gene range 2–10): PRKACB.
- chr1:84,244,334–84,397,831, 5 genes, copy number 10: NEDD8P1, AL359273.1, SAMD13, AL359273.2, UOX.
- chr1:87,620,803–88,685,204, 1 gene, copy number 17 (within-gene range 2–17): PKN2-AS1.
- chr1:88,313,153–88,578,201, 5 genes, copy number 11 (within-gene range 11–17): AL049861.1, RN7SL583P, AC093578.1, AC093578.2, RPL36AP10.
- chr1:93,921,268–94,121,148, 10 genes, copy number 9: CHCHD2P5, MTND4P11, MTND3P21, MTCO3P21, MTATP6P13, AL117351.2, MTCO2P21, MTCO1P21, AL117351.1, ABCA4.
- chr1:143,419,625–154,870,281, 490 genes, copy number 7–29 (broad region; genes not listed).
- chr1:155,120,490–155,885,199, 46 genes, copy number 6–12: Y_RNA, EFNA1, SLC50A1, DPM3, HMGN2P18, KRTCAP2, AL713999.2, TRIM46, MUC1, THBS3-AS1, MIR92B, THBS3, MTX1, AC234582.1, GBAP1, MTX1P1, GBA, FAM189B, SCAMP3, CLK2, HCN3, PKLR, FDPS, RUSC1-AS1, RUSC1, ASH1L, MIR555, RNU6-106P, ASH1L-IT1, RNU6-1297P, POU5F1P4, ASH1L-AS1, AL353807.4, DAP3P1, AL353807.1, AL353807.2, MSTO1, AL353807.3, AL353807.5, YY1AP1, DAP3, AL162734.1, MSTO2P, GON4L, AL139128.1, SYT11.
- chr1:157,573,747–158,186,427, 17 genes, copy number 5–14: FCRL4, AL135929.2, AL135929.1, FCRL3, AL356276.1, AL356276.2, VDAC1P9, FCRL2, FCRL1, CD5L, MRPS21P2, AL139010.1, KIRREL1, KIRREL1-IT1, LINC01704, ELL2P1, CD1D.
- chr1:158,254,424–158,686,715, 20 genes, copy number 5–12: CD1A, HMGN1P5, CD1C, CD1B, CD1E, OR10T2, OR10K2, OR10T1P, EI24P2, OR10K1, OR10R2, AL365440.1, OR10R3P, OR10R1P, HSP90AA3P, OR6Y1, OR6P1, OR10X1, OR10Z1, SPTA1.
- chr1:159,466,321–162,039,567, 128 genes, copy number 10–15 (within-gene range 3–15) (broad region; genes not listed).
- chr1:163,923,670–164,357,364, 4 genes, copy number 15: U3, NMNAT1P2, RNU5F-6P, HMGB3P6.
- chr1:165,400,922–168,075,843, 67 genes, copy number 17 (within-gene range 3–17) (broad region; genes not listed).
- chr1:168,178,962–169,104,907, 26 genes, copy number 10–17: TIPRL, RPL34P1, AL021397.1, SFT2D2, ANKRD36BP1, RNU6-1310P, TBX19, AL022100.1, MIR557, AL023755.1, AL022100.2, QRSL1P1, XCL2, AL031736.1, XCL1, AL031736.2, DPT, AL135926.1, AL031275.1, LINC00626, SUMO1P2, LINC00970, RPL29P7, AL031726.2, RNA5SP66, AL031726.1.
- chr2:38,814–26,244,672, 399 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr2:37,435,510–41,157,555, 58 genes, copy number 5: RNU6-1116P, AC006369.1, CDC42EP3, AC006369.2, AC010878.1, LINC00211, RMDN2, RMDN2-AS1, CYP1B1, CYP1B1-AS1, AC009229.4, AC009229.2, RNU6-951P, AC009229.3, AC009229.1, RPL7P12, GAPDHP25, ATL2, LINC02613, AC016995.1, LINC01883, RPLP0P6, AC011247.2, HNRNPLL, AC011247.1, GALM, AC074366.1, SRSF7, GEMIN6, TTC39DP, NPLP1, DHX57, ASS1P2, AC018693.1, MORN2, RNU6-851P, ARHGEF33, RN7SL96P, AC019171.1, SOS1, SOS1-IT1, RNU6-198P, HSPE1P13, Y_RNA, CDKL4, MAP4K3, AC007684.1, AC007684.2, MAP4K3-DT, TMEM178A, THUMPD2, SLC8A1-AS1, AC007253.1, SLC8A1, AC007877.1, AC007317.1, LINC01794, HNRNPA1P57.
- chr2:43,219,849–44,772,592, 28 genes, copy number 5: AC010883.3, ZFP36L2, LINC01126, AC010883.1, THADA, RNU6-958P, RN7SL531P, Y_RNA, PLEKHH2, C1GALT1C1L, AC011242.1, RN7SKP66, DYNC2LI1, ABCG5, ABCG8, LRPPRC, RNU6-1048P, RN7SL455P, AC019129.1, RNU6-566P, PDSS1P2, AC019129.2, PPM1B, AC013717.1, RPL12P19, SLC3A1, PREPL, CAMKMT.
- chr2:51,032,601–65,432,637, 229 genes, copy number 5 (broad region; genes not listed).
- chr2:69,396,113–76,595,678, 187 genes, copy number 5 (broad region; genes not listed).
- chr2:81,194,337–85,905,199, 78 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr2:92,006,680–100,676,038, 184 genes, copy number 5 (broad region; genes not listed).
- chr2:102,064,544–130,051,131, 449 genes, copy number 5 (broad region; genes not listed).
- chr2:145,294,277–242,175,634, 1,555 genes, copy number 5–6 (broad region; genes not listed).
- chr3:11,745–1,065,875, 13 genes, copy number 5: LINC01986, AC066595.1, CHL1-AS2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32, AC090044.1, AC087430.1, RN7SL120P.
- chr3:175,938,929–176,114,537, 5 genes, copy number 7: AC104640.1, ACTG1P23, EI24P1, AC104640.2, AC117434.1.
- chr5:58,453,982–58,863,414, 9 genes, copy number 6: PLK2, GAPT, AC008814.1, MIR548AE2, LINC02108, RAB3C, AC016642.1, RPL5P15, AC008852.1.
- chr6:25,726,063–28,633,594, 173 genes, copy number 8 (broad region; genes not listed).
- chr6:29,657,002–31,415,315, 145 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr6:32,439,878–33,457,544, 74 genes, copy number 8–22 (broad region; genes not listed).
- chr6:35,733,867–58,438,364, 444 genes, copy number 5–14 (broad region; genes not listed).
- chr6:106,969,831–108,165,854, 23 genes, copy number 5 (within-gene range 4–5): CD24, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12, SOBP, AL121957.1, AL096816.1, SCML4, SEC63, RNU6-437P, RPL23AP50, AL024507.2, AL024507.1, SNORA73, MTHFD2P3, RPL3P7, Z98200.1, OSTM1, Y_RNA, OSTM1-AS1.
- chr7:37,032–159,233,377, 2,933 genes, copy number 5–6 (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,494 genes, copy number 5 (broad region; genes not listed).
- chr9:60,914,407–64,440,180, 84 genes, copy number 6 (broad region; genes not listed).
- chr11:126,202,096–126,440,344, 15 genes, copy number 5 (within-gene range 3–5): RPUSD4, AP001893.1, FAM118B, RNU4-86P, RN7SL351P, SRPRA, FOXRED1, RPL35AP26, TIRAP, AP001318.1, AP001318.2, DCPS, GSEC, ST3GAL4, AP001318.3.
- chr13:37,481,467–37,598,844, 3 genes, copy number 5: LINC01048, LINC00547, POSTN.
- chr13:66,218,250–69,408,735, 27 genes, copy number 5: MIR4704, TRIM60P19, PCDH9, PCDH9-AS1, RNU7-87P, PCDH9-AS2, PCDH9-AS3, PCDH9-AS4, AL160254.1, RPSAP53, LINC00364, BCRP9, NPM1P22, OR7E111P, OR7E33P, ELL2P3, HNRNPA1P18, RPL37P21, RPS3AP52, RPL12P34, RN7SL761P, LINC00550, LINC02342, ZDHHC20P4, SNRPFP3, LINC00383, SRSF1P1.
- chr14:18,333,726–20,060,983, 89 genes, copy number 5 (broad region; genes not listed).
- chr14:36,213,200–36,679,362, 16 genes, copy number 5 (within-gene range 3–5): AL162511.1, RN7SKP21, MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9.
- chr20:87,250–16,053,197, 288 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:15,892,355–64,327,972, 1,107 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 85. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
